Surgical pathology report (de-identified scan), TCGA case TCGA-SC-A6LQ, project TCGA-MESO (Mesothelioma), tissue source site Memorial Sloan Kettering, specimen TCGA-SC-A6LQ-01A (Primary Tumor).

[page 1 of 5]
1CD-0-3

mesothelioma, epithelioid, malignant
9052/3

Site: pleura (R) C 38.4

fw 9/13/13

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age:) Y Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]

Clinical Diagnosis & History:
year old female, malignant mesothelioma epithelial type.

Specimens Submitted:

- 1: Right level four lymph nodes (fs)
- 2: Level seven lymph nodes
- 3: Level seven mediastinal lymph nodes #2 (fs)
- 4: Right pleura and diaphragm
- 5: Portion of right sixth rib
- 6: Right pleura
- 7: Pericardial nodule
- 8: Right level eight mediastinal lymph node

DIAGNOSIS:

1. Right level four lymph nodes (fs):
- Metastatic mesothelioma in one of eighteen lymph nodes (1/18)
2. Level seven lymph nodes:
- Metastatic mesothelioma in four of ten lymph nodes (4/10)
3. Level seven mediastinal lymph nodes #2 (fs):
- Metastatic mesothelioma in one of four lymph nodes (1/4)
4. Right pleura and diaphragm:
- Malignant mesothelioma, epithelioid type, see note
- The tumor invades into adipose tissue and skeletal muscle
- The tumor comes within 1 mm to the skeletal muscle margins
- Note: The tumor is morphologically similar to the biopsied malignant mesothelioma of the pleura. The tumor shows a micropapillary predominant pattern.
5. Portion of right sixth rib:
- Benign bone and bone marrow
6. Right pleura:
- Malignant mesothelioma, similar to part 4
7. Pericardial nodule:
- Malignant mesothelioma, similar to part 4

** Continued on next page **

[page 2 of 5]
SURGICAL PATHOLOGY REPORT
Patient: [REDACTED]
MRN: [REDACTED]
Account # [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

Page 2 of 5

8. Right level eight mediastinal lymph node:
- Metastatic mesothelioma in one of one lymph node (1/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:	Special Stain	Comment
Result	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Right level four lymph nodes" and consists of a piece of adipose tissue with multiple lymph nodes (12) ranging in size from 0.2 cm up to 1.5 cm. All identified lymph nodes are entirely submitted for frozen section.

Summary of sections:

FSC - transected, calcified lymph nodes, frozen section control
FSCB-lymph nodes, frozen section control
FSCC-lymph nodes, frozen section control

2). The specimen is received fresh, labeled "Level seven lymph nodes", and consists of piece of adipose tissue with multiple lymph nodes ranging in size from 1.5 cm - 0.3 cm. All identified lymph node are entirely submitted.

Summary of sections:

LN - lymph nodes

3). The specimen is received fresh for frozen section consultation, labeled "Level seven mediastinal lymph nodes # 2" and consists of four lymph nodes measuring from 0.5 cm up to 1 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

** Continued on next page **

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account # [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: [REDACTED]

Date of Report: [REDACTED]

Page 3 of 5

4). The specimen is received fresh, labeled "Right pleura and diaphragm", and consists of a pink-tan membranous, flat, tissue with focal areas of muscle (11.0 x 5.0 x 0.5 cm) and adipose tissue measuring 35 x 25 x 2.0 cm in total dimension. The membranous area is 90% involved by tumor in the form of multiple small nodules (0.1 to 4.0 cm), plaque-like masses, and a round large mass (7.0 x 5.0 x 2.0 cm). The rough surface area of the muscle is inked black and sections are taken here. The remaining specimen is representatively submitted. TPS was taken. The specimen has been photographed. The specimen is shown to

Summary of sections:

M - muscle area

RS - remaining specimen

ADD - additional specimen

5). The specimen is received fresh, labeled "Portion of right sixth rib" and consists of four segments of ribs measuring 22 x 2 x 0.6 cm in aggregate. Red, tan soft tissue is attached. The specimen is bisected to reveal a homogenous red tan granular and bony cut surface. The cortical surface appears intact, and no discrete lesions are noted. Each segment is representatively submitted for decalcification.

Summary of sections:

U - undesignated

6). The specimen is received in formalin, labeled "Right pleura", and consists of a piece of tan membranous, flat, tissue measuring 10.0 x 6.0 x 4.0 cm. Sectioning reveals multiple embedded mucinous nodules. The specimen is representatively submitted.

Summary of sections:

U - undesignated

7). The specimen is received in formalin, labeled "Pericardial nodule", and consists of a piece of tan soft tissue measuring 4 x 3.5 x 1.5 cm. There is an embedded 2.5 x 1.3 x 1.2 cm pink-tan, firm nodule. The specimen is entirely submitted.

Summary of sections:

U - undesignated

8). The specimen is received in formalin, labeled "Right level 8 mediastinal lymph node" and consists of one lymph node measuring 1.0 x 0.4 x 0.4 cm. The lymph node is bisected and entirely submitted.

** Continued on next page **

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #

Accession #:

Physician:

Service:

Date of Report:

Page 4 of 5

Summary of sections:

BLN - bisected lymph node

Summary of Sections:

Part 1: Right level four lymph nodes (fs)

Block	Sect.	Site	PCs
1		FSCA	1
1		FSCB	1
1		FSCC	1
1		FSCD	1

Part 2: Level seven lymph nodes

Block	Sect.	Site	PCs
2		Ln	2

Part 3: Level seven mediastinal lymph nodes #2 (fs)

Block	Sect.	Site	PCs
1		FSC	1

Part 4: Right pleura and diaphragm

Block	Sect.	Site	PCs
5		M	5
10		RS	10

Part 5: Portion of right sixth rib

Block	Sect.	Site	PCs
4		U	4

Part 6: Right pleura

Block	Sect.	Site	PCs
2		U	2

Part 7: Pericardial nodule

Block	Sect.	Site	PCs
1		U	1

Part 8: Right level eight mediastinal lymph node

Block	Sect.	Site	PCs
1		BLN	2

** Continued on next page **

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Thoracic

Date of Report: [REDACTED]

Page 5 of 5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Right level four lymph nodes (fs); metastatic malignant neoplasm
PERMANENT DIAGNOSIS: Same

3. FROZEN SECTION DIAGNOSIS: Level seven mediastinal lymph nodes #2 (fs); scattered malignant cells
PERMANENT DIAGNOSIS: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Right level four lymph nodes (fs); metastatic malignant neoplasm
PERMANENT DIAGNOSIS: Same

3. FROZEN SECTION DIAGNOSIS: Level seven mediastinal lymph nodes #2 (fs); scattered malignant cells
PERMANENT DIAGNOSIS: Same

** End of Report **

Source: NCI Genomic Data Commons file 34441f9a-4051-42c1-9d40-1a7f656ce52a (TCGA-SC-A6LQ.DDDDE403-9903-4955-8F1F-CB5266E2B2D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).